Somatic mutation profile of tumor specimen TARGET-10-PARXHT-03A (aliquot TARGET-10-PARXHT-03A-01D) from TARGET case TARGET-10-PARXHT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,106 days).
Specimen TARGET-10-PARXHT-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12905367-a8c7-4567-9f94-3c2661859fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARXHT-10A (Blood Derived Normal), aliquot TARGET-10-PARXHT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edbddf17-689c-486b-b191-753058ad4fe1

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, Intron 3, Splice Site 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.7117G>A p.A2373T | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.292); catalogued as rs200387258; called by muse, mutect2, varscan2
- ATP10B | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs754223933, COSV58777854; called by muse, mutect2, varscan2
- CADPS2 | c.3038T>C p.F1013S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1240242186; called by muse, mutect2, varscan2
- FBXW5 | c.1324_1326del p.E442del | In Frame Del (DEL) | VAF 40/114 reads (35%) | catalogued as rs765513807; called by pindel, varscan2
- GRIN1 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV59292546; called by muse, mutect2, varscan2
- IRS2 | c.3148G>A p.V1050I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs771232244; called by muse, mutect2, varscan2
- KIF1A | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.919); catalogued as rs556945776; called by muse, mutect2, varscan2
- NPHS2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62636291; called by muse, mutect2
- PTEN | c.738delinsCCT p.P248Yfs*9 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | catalogued as COSV64294002, COSV64297361, COSV64304156; called by pindel, varscan2*
- RXFP4 | c.809_831del p.V270Afs*25 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs1201562885; called by mutect2, pindel
- TMPRSS6 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758296017, COSV100696189; called by muse, mutect2, varscan2
- ALPL | c.785G>T p.R262I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CALM2 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.683); called by muse, varscan2
- CSMD2 | c.6224-1G>T p.X2075_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- GUCY1A2 | c.996G>T p.M332I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.131); called by muse, mutect2
- HERC1 | c.3136G>T p.V1046F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- HES6 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- HPSE | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MGAT4A | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- NTAQ1 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- NUP133 | c.666G>T p.L222F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PTEN | c.833_834insGAGGGGAAATCCATT p.T277_F278insLRGNP | In Frame Ins (INS) | VAF 10/53 reads (19%) | called by mutect2, pindel
- SKAP2 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2
- STON1 | c.1022C>A p.A341E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.215); called by mutect2, varscan2
- TYK2 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- UBN1 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZNF74 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, varscan2
- CD300E | c.30C>A p.L10= | Silent (SNP) | VAF 23/47 reads (49%) | called by muse, varscan2
- CMTM4 | c.198G>T p.L66= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- LRRC61 | c.72C>A p.R24= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- CTBP2 | c.59-2131G>A | Intron (SNP) | VAF 59/107 reads (55%) | catalogued as rs574762059; called by muse, mutect2, varscan2
- DLG2 | c.1978+855G>A | Intron (SNP) | VAF 15/88 reads (17%) | catalogued as rs755585601; called by muse, mutect2, varscan2
- MYT1 | c.1847-53C>A | Intron (SNP) | VAF 3/29 reads (10%) | catalogued as rs754181419; called by muse, mutect2
- PDE1C | c.*1G>A | 3'UTR (SNP) | VAF 19/30 reads (63%) | called by muse, varscan2
